Somatic mutation profile of tumor specimen TCGA-DJ-A13U-01A (aliquot TCGA-DJ-A13U-01A-11D-A10S-08) from TCGA case TCGA-DJ-A13U, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 60.6 years (22,130 days).
Specimen TCGA-DJ-A13U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf944f0b-abda-43bd-8b05-47a46db46b21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A13U-10A (Blood Derived Normal), aliquot TCGA-DJ-A13U-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0500829c-5bb7-46ae-830b-a23cadb1159f

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 7, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- C16orf72 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV59916703; called by muse, mutect2
- PPP3R2 | c.20A>T p.Y7F | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV62456578; called by muse, mutect2, varscan2
- RNF139 | c.1627A>G p.I543V | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.283); catalogued as COSV52681209; called by muse, mutect2, varscan2
- SDAD1 | c.1400A>G p.Y467C | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62403468; called by muse, mutect2
- TCN2 | c.395A>G p.K132R | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53192369; called by muse, mutect2, varscan2
- TRAF4 | c.279T>A p.S93R | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV52047377; called by muse, mutect2, varscan2
- AGA | c.489C>T p.C163= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV52807165; called by muse, mutect2
- COL27A1 | c.5274G>A p.E1758= | Silent (SNP) | VAF 118/309 reads (38%) | catalogued as COSV61929211; called by muse, mutect2, varscan2
- FGR | c.300G>A p.K100= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV100925871, COSV64969657; called by muse, mutect2, varscan2
- NCAM2 | c.1545C>A p.S515= | Silent (SNP) | VAF 8/101 reads (8%) | catalogued as COSV53061985, COSV53083359; called by muse, mutect2
